HCMI case HCM-CSHL-0699-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/f58c43fb-3ed2-4efa-b212-be47475b0717

Demographics
Sex at birth: female; Days to birth: -25,550 days (70.0 years before the index date); Year of birth: 1949; Vital status: Alive.

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C56; Tissue or organ of origin: Ovary; Classification of tumor: primary; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Sites of involvement: Liver / Ovary, Right.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/6; ICD-10 code: C78.7; Tissue or organ of origin: Ovary; Site of resection or biopsy: Liver; Classification of tumor: metastasis.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 158 days; Disease response: Complete Response; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 113 kg; Height: 168 cm; BMI: 40.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-CSHL-0699-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0699-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
